Somatic mutation profile of cancer-model specimen HCM-SANG-0280-C18-85A (3D Organoid; aliquot HCM-SANG-0280-C18-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0280-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G3.
Specimen HCM-SANG-0280-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fccfe956-c229-4fe4-bc13-56a65d131d42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0280-C18-10A (Blood Derived Normal), aliquot HCM-SANG-0280-C18-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96d85ae0-8ac3-4b6a-826c-3f2703463167

The open-access MAF lists 143 somatic variants for this specimen: 113 protein-altering or splice-affecting, 27 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 27, Nonsense Mutation 6, Splice Region 3, Intron 2, Frame Shift Del 2, In Frame Del 1, 5'Flank 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 165/165 reads (100%) | catalogued as rs587779783, CM960067, COSV57322578; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 223/223 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.379C>T p.H127Y | Missense Mutation (SNP) | VAF 319/487 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757422086; called by muse, mutect2, varscan2
- ADAMTS16 | c.2958C>A p.C986* | Nonsense Mutation (SNP) | VAF 242/547 reads (44%) | catalogued as rs761895343; called by muse, mutect2, varscan2
- ADGRB3 | c.4354C>T p.R1452W | Missense Mutation (SNP) | VAF 184/306 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs1197657726, COSV53232994; called by muse, mutect2, varscan2
- AFAP1L2 | c.811G>A p.G271S | Missense Mutation (SNP) | VAF 99/316 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.131); catalogued as rs140344453, COSV58414514; called by muse, mutect2, varscan2
- ALPI | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 273/524 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs540160192, COSV55014117; called by muse, mutect2, varscan2
- AMER1 | c.1921C>T p.R641* | Nonsense Mutation (SNP) | VAF 453/453 reads (100%) | catalogued as COSV57654119; called by muse, mutect2, varscan2
- ANKMY1 | c.446A>G p.D149G | Missense Mutation (SNP) | VAF 71/336 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs765852536; called by muse, mutect2, varscan2
- APOA4 | c.48C>T p.A16= | Splice Region (SNP) | VAF 91/373 reads (24%) | catalogued as rs200493372; called by muse, mutect2, varscan2
- BAHCC1 | c.7018C>T p.R2340C | Missense Mutation (SNP) | VAF 54/1092 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs782380801; called by muse, mutect2
- BCL9L | c.1225C>T p.R409W | Missense Mutation (SNP) | VAF 279/541 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1295612684, COSV52681688; called by muse, mutect2, varscan2
- C4orf50 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 355/719 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.124); catalogued as rs1203718151; called by muse, mutect2, varscan2
- CCDC112 | c.1096C>G p.L366V | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.146); catalogued as rs1474246645; called by muse, mutect2
- CEP104 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 87/306 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764366578, COSV58215086; called by muse, mutect2, varscan2
- DBH | c.1247C>G p.T416S | Missense Mutation (SNP) | VAF 108/394 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.547); catalogued as rs148332995; called by muse, mutect2, varscan2
- DCSTAMP | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 105/787 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs566008351, COSV52576605; called by muse, mutect2, varscan2
- DLG2 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 216/459 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs150156552, COSV54627336; called by muse, mutect2, varscan2
- EFCAB6 | c.2764C>T p.R922W | Missense Mutation (SNP) | VAF 100/336 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs549978922; called by muse, mutect2, varscan2
- EPHB6 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 466/939 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1240703539; called by muse, mutect2, varscan2
- FAM163A | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 209/340 reads (61%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs768342510, COSV59203433; called by muse, mutect2, varscan2
- FAM184A | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 362/557 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV58859017; called by muse, mutect2, varscan2
- FFAR2 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 227/477 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs143092631; called by muse, mutect2, varscan2
- FIGN | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 81/390 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as rs770886664; called by muse, mutect2, varscan2
- GRAMD1B | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 323/629 reads (51%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.84); catalogued as rs1198666415, COSV100455359; called by muse, mutect2, varscan2
- GUCY1B1 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 129/301 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1334359082, COSV52378630; called by muse, mutect2, varscan2
- GULP1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 196/414 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs749785708; called by muse, mutect2, varscan2
- HNF4A | c.1084G>A p.G362S | Missense Mutation (SNP) | VAF 246/701 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as rs555432665; called by muse, mutect2, varscan2
- HP | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs369571464; called by muse, mutect2, varscan2
- HS3ST2 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 427/642 reads (67%) | SIFT tolerated (0.51); PolyPhen benign (0.069); catalogued as rs760879006, COSV54461014; called by muse, varscan2
- IGSF21 | c.1247A>G p.Q416R | Missense Mutation (SNP) | VAF 273/425 reads (64%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.973); catalogued as rs781185535; called by muse, mutect2, varscan2
- INTS10 | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 140/140 reads (100%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as rs201728325; called by muse, varscan2
- KIF12 | c.1366C>T p.R456C (on ENST00000640217; = p.R318C on NM_138424.1) | Missense Mutation (SNP) | VAF 131/400 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs774477975, COSV65117601; called by muse, mutect2, varscan2
- LRRC46 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 153/720 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373351041; called by muse, mutect2, varscan2
- MAP7D1 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 84/265 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202003056; called by muse, mutect2, varscan2
- MATN4 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 604/973 reads (62%) | PolyPhen probably damaging (1); catalogued as rs1018392731; called by muse, mutect2, varscan2
- MDGA2 | c.1360C>T p.R454W (on ENST00000399232 / NM_001113498.2; = p.R156W on NM_182830.4) | Missense Mutation (SNP) | VAF 213/436 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs775365673, COSV62078893; called by muse, mutect2, varscan2
- MSR1 | c.407T>C p.M136T | Missense Mutation (SNP) | VAF 52/258 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs746729873; called by muse, mutect2, varscan2
- MTSS1 | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 164/638 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780128073, COSV52674192; called by muse, mutect2
- NPAP1 | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 256/367 reads (70%) | SIFT tolerated (0.13); PolyPhen benign (0.123); catalogued as rs150016698, COSV61504101; called by muse, mutect2, varscan2
- OPRK1 | c.350C>T p.T117M | Missense Mutation (SNP) | VAF 332/573 reads (58%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.836); catalogued as rs527490946, COSV55568518; called by muse, mutect2, varscan2
- OR4X1 | c.150C>A p.S50R | Missense Mutation (SNP) | VAF 271/531 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1419895369; called by muse, mutect2, varscan2
- PAPPA2 | c.5258A>G p.Y1753C | Missense Mutation (SNP) | VAF 196/296 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753712379, COSV62795384; called by muse, mutect2, varscan2
- PLAT | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 226/796 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as rs765577929; called by muse, mutect2, varscan2
- PPL | c.2212G>A p.G738S | Missense Mutation (SNP) | VAF 102/643 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs765551088, COSV62044611; called by muse, mutect2, varscan2
- PPL | c.1210G>A p.V404M | Missense Mutation (SNP) | VAF 124/812 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs762778772; called by muse, mutect2, varscan2
- RNF223 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 184/661 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs574509653; called by muse, mutect2, varscan2
- SCART1 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 530/808 reads (66%) | SIFT tolerated (0.45); PolyPhen benign (0.041); catalogued as rs934764878; called by muse, mutect2, varscan2
- SDK2 | c.109G>A p.V37M | Missense Mutation (SNP) | VAF 103/442 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs747655108; called by muse, mutect2, varscan2
- SORCS2 | c.1892G>T p.R631L | Missense Mutation (SNP) | VAF 186/398 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs774161295, COSV61163963; called by muse, mutect2, varscan2
- SPOCD1 | c.2944C>T p.R982C | Missense Mutation (SNP) | VAF 206/338 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759296444; called by muse, mutect2, varscan2
- SSTR1 | c.908C>T p.T303M | Missense Mutation (SNP) | VAF 257/529 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.157); catalogued as rs755345631; called by muse, mutect2, varscan2
- SYNE1 | c.17956C>G p.L5986V (on ENST00000367255 / NM_182961.4; = p.L5915V on NM_033071.3) | Missense Mutation (SNP) | VAF 137/432 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99556383; called by muse, mutect2, varscan2
- THBS2 | c.1880G>A p.R627K | Missense Mutation (SNP) | VAF 394/619 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64682742; called by muse, mutect2, varscan2
- TMEM187 | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 649/649 reads (100%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs782106515, COSV64141676; called by muse, mutect2, varscan2
- TNXB | c.7242C>A p.H2414Q (on ENST00000647633; = p.H2167Q on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 214/645 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.095); catalogued as COSV64473550; called by muse, mutect2, varscan2
- TPTE | c.571A>G p.T191A (on ENST00000618007 / NM_199261.4; = p.T173A on NM_199259.4) | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0.017); catalogued as rs751838173; called by muse, mutect2, varscan2
- TRIM22 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 144/291 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as rs1024408042, COSV66090783; called by muse, varscan2
- VSTM2L | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 440/748 reads (59%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as rs1162018185, COSV65096082; called by muse, mutect2, varscan2
- WDR7 | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 166/166 reads (100%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.885); catalogued as rs1020220351, COSV99589730; called by muse, mutect2, varscan2
- ABCC9 | c.1821G>C p.E607D | Missense Mutation (SNP) | VAF 119/196 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ABCG4 | c.836G>T p.C279F | Missense Mutation (SNP) | VAF 158/323 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ALDH5A1 | c.728T>A p.L243H | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ALG12 | c.1055_1060delinsC p.L352Pfs*41 | Frame Shift Del (DEL) | VAF 240/437 reads (55%) | called by pindel, varscan2*
- ANKRD34A | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 332/503 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- ANKRD6 | c.1022C>A p.S341* | Nonsense Mutation (SNP) | VAF 163/264 reads (62%) | called by muse, mutect2, varscan2
- AVPR1A | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 132/403 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BICC1 | c.2533+4A>T | Splice Region (SNP) | VAF 226/338 reads (67%) | called by muse, mutect2, varscan2
- C14orf39 | c.955A>C p.K319Q | Missense Mutation (SNP) | VAF 111/286 reads (39%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- C2orf16 | c.905C>A p.S302* | Nonsense Mutation (SNP) | VAF 188/404 reads (47%) | called by muse, mutect2, varscan2
- C8orf34 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 354/629 reads (56%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- CACNA1H | c.5886G>A p.L1962= | Splice Region (SNP) | VAF 194/590 reads (33%) | called by muse, mutect2, varscan2
- CALR | c.823T>C p.W275R | Missense Mutation (SNP) | VAF 195/398 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDC42BPA | c.790G>C p.D264H | Missense Mutation (SNP) | VAF 220/355 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK19 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 63/346 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- CHDH | c.584A>G p.N195S | Missense Mutation (SNP) | VAF 422/424 reads (100%) | SIFT tolerated (0.31); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- COL14A1 | c.3166T>A p.Y1056N | Missense Mutation (SNP) | VAF 365/659 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- DIAPH2 | c.1427A>G p.D476G | Missense Mutation (SNP) | VAF 144/145 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DNAH7 | c.4240G>C p.E1414Q | Missense Mutation (SNP) | VAF 105/192 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC2H1 | c.9796G>A p.E3266K | Missense Mutation (SNP) | VAF 94/187 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EIF4E1B | c.391A>G p.R131G | Missense Mutation (SNP) | VAF 236/439 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- ERC1 | c.948G>C p.L316F | Missense Mutation (SNP) | VAF 151/627 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FKRP | c.1235A>G p.H412R | Missense Mutation (SNP) | VAF 345/677 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- HIC2 | c.1646C>T p.T549M | Missense Mutation (SNP) | VAF 195/566 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOOK1 | c.1775T>A p.L592H | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HTR1D | c.587_589del p.S196del | In Frame Del (DEL) | VAF 242/394 reads (61%) | called by mutect2, pindel, varscan2
- IFI16 | c.1653T>A p.S551R (on ENST00000295809 / NM_001364867.2; = p.S495R on NM_001206567.2) | Missense Mutation (SNP) | VAF 76/282 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- KCNMA1 | c.1019G>T p.W340L | Missense Mutation (SNP) | VAF 14/455 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- LHX1 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 153/712 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MYH7B | c.1459A>T p.I487F | Missense Mutation (SNP) | VAF 313/819 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYO18B | c.2009G>A p.C670Y | Missense Mutation (SNP) | VAF 116/415 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYPN | c.1595T>C p.V532A | Missense Mutation (SNP) | VAF 69/201 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NXF1 | c.1691C>T p.S564F | Missense Mutation (SNP) | VAF 240/519 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- PABPC4L | c.191C>G p.A64G | Missense Mutation (SNP) | VAF 149/314 reads (47%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- PACRG | c.259C>A p.H87N | Missense Mutation (SNP) | VAF 119/342 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- PCNT | c.6307G>A p.A2103T | Missense Mutation (SNP) | VAF 200/434 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PCNT | c.6308C>A p.A2103E | Missense Mutation (SNP) | VAF 201/435 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PTCD1 | c.1734G>A p.M578I | Missense Mutation (SNP) | VAF 147/275 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RBM46 | c.1030C>G p.L344V | Missense Mutation (SNP) | VAF 204/402 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC12A2 | c.821dup p.Y275Vfs*6 | Frame Shift Ins (INS) | VAF 116/295 reads (39%) | called by mutect2, pindel, varscan2
- SLC9C2 | c.2179C>G p.L727V | Missense Mutation (SNP) | VAF 14/263 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLCO1B3 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 120/195 reads (62%) | called by muse, mutect2, varscan2
- SOX9 | c.1079del p.P360Rfs*23 | Frame Shift Del (DEL) | VAF 287/737 reads (39%) | called by mutect2, pindel, varscan2
- SRP72 | c.1699G>C p.D567H | Missense Mutation (SNP) | VAF 119/234 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SYMPK | c.611C>G p.P204R | Missense Mutation (SNP) | VAF 244/498 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM271 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 147/815 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPCN2 | c.634T>C p.S212P | Missense Mutation (SNP) | VAF 152/374 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- TRIM49 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 46/712 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TRIP4 | c.1358_1358+12del p.X453_splice | Splice Site (DEL) | VAF 39/167 reads (23%) | called by mutect2, pindel, varscan2
- USH2A | c.13280G>A p.G4427E | Missense Mutation (SNP) | VAF 141/384 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- VASP | c.212A>G p.K71R | Missense Mutation (SNP) | VAF 200/438 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- ZNF628 | c.2786C>T p.T929M | Missense Mutation (SNP) | VAF 319/666 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF814 | c.1563G>T p.E521D | Missense Mutation (SNP) | VAF 234/502 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.308); called by mutect2, varscan2
- ADCY8 | c.3426C>T p.D1142= | Silent (SNP) | VAF 89/783 reads (11%) | catalogued as COSV99652436; called by muse, mutect2, varscan2
- BIRC6 | c.11769A>G p.Q3923= | Silent (SNP) | VAF 106/232 reads (46%) | catalogued as rs1167674937; called by muse, mutect2, varscan2
- BOC | c.3300G>A p.G1100= | Silent (SNP) | VAF 268/276 reads (97%) | catalogued as rs1420446399, COSV99848436; called by muse, varscan2
- BROX | c.816G>A p.R272= | Silent (SNP) | VAF 54/182 reads (30%) | catalogued as rs755135349; called by muse, mutect2, varscan2
- CALD1 | c.999G>A p.E333= | Silent (SNP) | VAF 288/614 reads (47%) | catalogued as COSV62654534; called by muse, mutect2, varscan2
- FBXL12 | c.627G>T p.V209= | Silent (SNP) | VAF 22/784 reads (3%) | catalogued as rs1568341272; called by muse, mutect2
- FGF12 | c.294C>T p.D98= (on ENST00000454309 / NM_021032.5; = p.D36= on NM_004113.6) | Silent (SNP) | VAF 218/221 reads (99%) | catalogued as rs555759767, COSV53160763; called by muse, varscan2
- GABRA5 | c.1311C>T p.F437= | Silent (SNP) | VAF 96/301 reads (32%) | catalogued as rs762670835, COSV100165962, COSV59478642; called by muse, mutect2, varscan2
- HDC | c.399C>T p.F133= | Silent (SNP) | VAF 98/310 reads (32%) | called by muse, mutect2, varscan2
- HOXC8 | c.120C>T p.Y40= | Silent (SNP) | VAF 190/550 reads (35%) | catalogued as rs376375995; called by muse, mutect2, varscan2
- JMJD1C | c.3354C>T p.Y1118= | Silent (SNP) | VAF 175/293 reads (60%) | catalogued as rs758928810, COSV59513782; called by muse, mutect2, varscan2
- KMT2A | c.3489G>T p.V1163= | Silent (SNP) | VAF 171/380 reads (45%) | catalogued as rs992898962; called by muse, mutect2, varscan2
- LGR5 | c.1152T>C p.N384= | Silent (SNP) | VAF 73/224 reads (33%) | called by muse, mutect2, varscan2
- MGAT4D | c.360T>C p.P120= | Silent (SNP) | VAF 100/220 reads (45%) | called by muse, mutect2, varscan2
- NWD2 | c.549C>T p.S183= | Silent (SNP) | VAF 59/293 reads (20%) | called by muse, mutect2, varscan2
- OR2L5 | c.927G>T p.S309= | Silent (SNP) | VAF 35/150 reads (23%) | catalogued as rs528003385, COSV62364369; called by muse, mutect2, varscan2
- RNF215 | c.540C>A p.V180= | Silent (SNP) | VAF 150/259 reads (58%) | called by muse, mutect2, varscan2
- S1PR1 | c.519C>T p.I173= | Silent (SNP) | VAF 128/440 reads (29%) | called by muse, mutect2, varscan2
- SCN1A | c.135C>T p.D45= | Silent (SNP) | VAF 219/424 reads (52%) | catalogued as rs201985242; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- SCUBE3 | c.693C>T p.T231= | Silent (SNP) | VAF 141/401 reads (35%) | catalogued as rs766128386, COSV51457637, COSV99234935; called by muse, mutect2, varscan2
- SDK1 | c.3483G>A p.P1161= | Silent (SNP) | VAF 270/529 reads (51%) | catalogued as rs771307855, COSV101270059; called by muse, mutect2, varscan2
- SULT1A3 | c.30G>A p.P10= | Silent (SNP) | VAF 66/509 reads (13%) | catalogued as rs1414473902; called by muse, mutect2, varscan2
- TDRKH | c.456G>A p.K152= | Silent (SNP) | VAF 232/359 reads (65%) | called by muse, mutect2, varscan2
- TMC2 | c.990C>T p.I330= | Silent (SNP) | VAF 211/402 reads (52%) | catalogued as rs779129279; called by muse, mutect2, varscan2
- TUBB4A | c.690G>A p.S230= | Silent (SNP) | VAF 384/808 reads (48%) | catalogued as rs1368586638, COSV51168489; called by muse, mutect2, varscan2
- USP35 | c.1452G>T p.L484= | Silent (SNP) | VAF 182/394 reads (46%) | catalogued as rs551443747; called by muse, mutect2, varscan2
- ZNF284 | c.798G>A p.K266= | Silent (SNP) | VAF 136/300 reads (45%) | catalogued as rs1314455201; called by muse, mutect2, varscan2
- C4orf50 | chr4:5990167 G>A | 5'Flank (SNP) | VAF 165/339 reads (49%) | called by muse, mutect2, varscan2
- CTHRC1 | c.372+66T>C | Intron (SNP) | VAF 46/324 reads (14%) | called by muse, mutect2, varscan2
- MUCL3 | c.946+1018T>C | Intron (SNP) | VAF 320/949 reads (34%) | catalogued as rs1423588481, COSV58518354; called by muse, mutect2, varscan2
